Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RE-01A (Primary Tumor).

DEPARTMENT OF PATHOLOGY
SURGICAL PATHOLOGY REPORT

Material
Submitted:
Clinical
History:
Clinical
Diagnosis:
Operating
Surgeon:

Right breast tissue.

100-0-3
Carcinoma infiltrating ductal, NOS
8500/3
Path: Site Code: breast, upper
outer quadrant C50.4

11/7/11

W

CQCF: breast, NOS C50.4

Pathology Number

Gross Examination:

The specimen is received in a single container labeled with the patient's name, history number, date and "right breast tissue". Received is a right breast weighing 982 grams. The breast measures 19.0 x 17.0 x 4.0 cm. in greatest dimensions and there is an axillary tail that measures 11.0 x 6.0 x 2.0 cm. in greatest dimensions. The skin ellipse on the surface of the breast is unremarkable. There is no evidence of induration or ulceration. The nipple is likewise unremarkable with no retraction of the nipple, induration or ulceration. There is no incision noted on the skin ellipse. Palpation of the breast reveals a firm nodule in the upper outer quadrant of the breast that measures 2.0 x 2.0 x 1.5 cm. in greatest dimensions. The nodule is located in the approximately ten o'clock position with relation to the nipple and measures 5.5 cm. from the nipple. On sectioning the mass is revealed to be firm and whitish-tan. The tumor comes to within 3.5 cm. of the deep margin of the specimen. The deep margin is grossly not involved by tumor. A section of the deep margin underneath the tumor is taken and placed in Block I. The tumor comes to within 0.5 cm. of the skin. Sections of the tumor are taken and placed in Blocks II, III, and IV. A section through the nipple is placed in Block V. Serial sectioning of the remainder of the breast tissue does not reveal any other firm masses. A representative section from the lower outer quadrant is taken and placed in Block VI. A section from the lower inner quadrant is placed in Block VII and a section from the upper inner quadrant of breast tissue is placed in Block VIII. A section of skin overlying the tumor is placed in Block IX. The axillary tail is divided into the standard three areas and lymph nodes from the first area are placed in Block X. Lymph nodes from the second level are placed in Block XI. Lymph node candidates from the third level are placed in Block XII. **Addendum: It should be noted that tissue has been sent from the tumor for ER/PR receptors.**

DIAGNOSIS:

"RIGHT BREAST", MASTECTOMY:

A.) BREAST WITH INTRADUCTAL AND INFILTRATING DUCTAL CARCINOMA N.S.A.B.P. NUCLEAR GRADE POORLY DIFFERENTIATED HISTOLOGIC GRADE 3 OF 3. MARGINS ARE FREE OF TUMOR.

B.) SEVERE DUCTAL EPITHELIAL HYPERPLASIA.

C.) FOURTEEN AXILLARY LYMPH NODES. NO CANCER SEEN.

Dual/Synchronous Primary Note(s)		☒

Source: NCI Genomic Data Commons file a8f6c36b-67e4-4924-abdf-2a25fa07f9bb (TCGA-B6-A0RE.5607C6CE-21D5-495E-9174-85F1E2E0CB9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).